Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A0JM, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A0JM-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis & History:

y/o female with right lower inner quadrant carcinoma IDC/DCIS with microcalcifications. Right 3:00 => IDC poorly differentiated; DCIS with microcalcification.

Specimens Submitted:

- 1: SP: Sentinel node #1, level one, right axilla (fs)
- 2: SP: Sentinel node #2, level one, right axilla (fs)
- 3: SP: Sentinel node #3, level two, right axilla (fs)
- 4: SP: Right breast and axillary contents levels 1, 2 and 3

DIAGNOSIS:

- 1) LYMPH NODE, SENTINEL #1 LEVEL I RIGHT AXILLA; BIOPSY:
- METASTATIC CARCINOMA IN ONE OUT OF SIX LYMPH NODES (1/6).
- THERE IS NO EXTRANODAL EXTENSION OF CARCINOMA.
- 2) LYMPH NODE, SENTINEL #2 LEVEL I RIGHT AXILLA; BIOPSY:
- METASTATIC CARCINOMA IN ONE OF ONE LYMPH NODE (1/1). (SEE NOTE)
- NO EXTRANODAL EXTENSION SEEN.

NOTE: THE METASTASIS IS PRESENT ON DEEPER LEVEL PERMANENT SECTION ONLY.

- 3) LYMPH NODE, SENTINEL #3 LEVEL II RIGHT AXILLA; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).
- 4) BREAST AND AXILLARY CONTENTS, RIGHT LEVELS I, II, AND III; MASTECTOMY:
- MULTIPLE FOCI OF INVASIVE DUCTAL CARCINOMA, NOS TYPE, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE III/III (MARKED VARIATION IN SIZE AND SHAPE), RANGING IN SIZE FROM 0.1 CM UP TO 3 CM.
- DUCTAL CARCINOMA IN SITU (DCIS) IS ALSO IDENTIFIED, SOLID, CRIBRIFORM, AND MICROPAPILLARY TYPES WITH HIGH NUCLEAR GRADE AND MODERATE NECROSIS.
- LOBULAR INVOLVEMENT BY DCIS IS PRESENT.
- THE DCIS CONSTITUTES >= 25% OF THE TOTAL TUMOR MASS, AND IS PRESENT ADMIXED WITH AND AWAY FROM THE INVASIVE COMPONENT.
- THE INVASIVE CARCINOMA IS LOCATED IN THE LOWER OUTER QUADRANT AND LOWER INNER QUADRANT.
- THE DCIS IS LOCATED IN THE LOWER OUTER QUADRANT AND LOWER INNER QUADRANT.
- DCIS INVOLVES THE LARGE LACTIFEROUS DUCTS.

** Continued on next page **

ICD-0-3

Carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 lw 10/22/11

[page 2 of 5]
- CALCIFICATIONS ARE PRESENT IN BOTH THE IN SITU AND INVASIVE CARCINOMA.
- VASCULAR INVASION IS PRESENT.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY INVASIVE CARCINOMA IS IDENTIFIED.
- RARE FOCI OF DCIS/IN SITU CARCINOMA ARE CLOSE (1 MM) TO THE FOLLOWING SURGICAL MARGIN: DEEP.
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.
- THE ATTACHED SKELETAL MUSCLE IS NEGATIVE FOR TUMOR.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF POSITIVE LYMPH NODES IN RELATION TO THE TOTAL NUMBER OF LYMPH NODES EXAMINED): LEVEL I: 0/13; LEVEL II: 0/9; AND LEVEL III: 0/2.
- RESULTS OF SPECIAL STAINS (ER, PR, HER2-NEU) WILL BE REPORTED AS AN ADDENDUM.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	ER-C	
	PR-C	
	HER2-C	
	IMM RECUT	
	NEG CONT	

Gross Description:
MD

1). The specimen is received fresh for frozen section consultation, labeled "Sentinel node number one, level 1, right axilla" and consists of 7 lymph nodes and measure 3.5 x 2.6 x 1.0 cm in aggregate. One lymph node is blue and has been bisected, and the lymph nodes are entirely submitted in two cassettes.

Summary of sections:

FSCA--frozen section control A
FSCB--frozen section control B

2). The specimen is received fresh for frozen section consultation, labeled "Sentinel node number two, level 1, left axilla" and consists of a soft lymph node measuring 0.6 x 0.5 x 0.5 cm, bisected and entirely submitted for frozen section.

Summary of sections:

** Continued on next page **

[page 3 of 5]
FSC-frozen section control

PA

3). The specimen is received fresh for frozen section consultation, labeled "Sentinel node number three, level 2, right axilla" and consists of two soft tan lymph nodes totaling 2.0 x 1.2 x 0.6 cm, entirely submitted for frozen section.

Summary of sections:

FSC-frozen section control

, MD

4). The specimen is received fresh in a container, labeled "Right breast and axillary contents levels 1, 2 and 3 with tags attached". The specimen consists of a mastectomy measuring 30 x 19 x 3 cm. That axillary tail measures 13 x 8 x 2 cm. The overlying ellipse of skin measures 10 x 3 cm. No scar can be identified on the skin. The nipple measures 1 x 1 cm and it is grossly unremarkable. The deep resection margin is inked blue. The specimen is serially sectioned revealing a pinkish red, relatively well-circumscribed and firm lesion measuring 3 x 1.5 x 1 cm which closely abuts the inked resection margin. The lesion is 2 cm away from the skin. The lesion is located in the lower inner quadrant. Surrounding the lesion, are areas of fibrosis which show punctate areas of cheesy necrosis. Away from this lesion, in the lower outer quadrant is a vaguely defined area of fibrosis and nodularity. Approximate measurements of this area are 10 x 6 cm. The upper inner and outer quadrants show mainly fatty tissue. An axillary dissection is performed revealing 3 level one lymph nodes, 4 level two lymph nodes and 2 level three lymph nodes.

Summary of sections:

TRM-tumor in relation to inked resection margin

TRS-tumor in relation to skin

LIQ-lower inner quadrant.

LOQ-lower outer quadrant

UOQ-upper outer quadrant

UIQ-upper inner quadrant

N-nipple

L1-level one lymph nodes

L2-level two lymph nodes

L3-level three lymph nodes.

Summary of Sections:

Part 1: SP: Sentinel node #1, level one, right axilla (fs) (

Block	Sect.	Site	PCs	
1		{not entered}		1
1		fsc	1	

** Continued on next page **

[page 4 of 5]
Part 2: SP: Sentinel node #2, level one, right axilla (fs)

Block	Sect.	Site	PCs
1		fsc	1

Part 3: SP: Sentinel node #3, level two, right axilla (fs)

Block	Sect.	Site	PCs
1		fsc	1

Part 4: SP: Right breast and axillary contents levels 1, 2 and 3

Block	Sect.	Site	PCs
1		l1	1
1		l2	1
1		l3	1
11		liq	11
15		loq	15
1		n	1
3		trm	3
1		trs	1
1		uiq	1
1		uoq	1

Procedures/Addenda:

Addendum

Date Ordered:

Status: Signed Out

Date Complete:

By:

Date Reported:

Addendum Diagnosis

ADDENDUM

SITE; RIGHT BREAST

PART #4.

ER: 90% OF NUCLEAR STAINING WITH MODERATE INTENSITY.

PR: 1% OF NUCLEAR STAINING WITH MODERATE TO WEAK INTENSITY.

HER2/NEU (HERCEPT): POSITIVE (STAINING INTENSITY OF 3+).

MD

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

** Continued on next page **

[page 5 of 5]
- 1) FROZEN SECTION DIAGNOSIS: METASTATIC CARCINOMA (SLIDE B).
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS: NEGATIVE LYMPH NODE
PERMANENT DIAGNOSIS: SEE FINAL DIAGNOSIS
- 3) FROZEN SECTION DIAGNOSIS: NEGATIVE LYMPH NODE
PERMANENT DIAGNOSIS: SAME

** End of Report **

Source: NCI Genomic Data Commons file bb76c980-f653-41bf-a108-654a903f100e (TCGA-AO-A0JM.3023C34B-CF59-43EA-9241-33B738D19B05.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).